Somatic mutation profile of tumor specimen TCGA-58-8393-01A (aliquot TCGA-58-8393-01A-11D-2323-08) from TCGA case TCGA-58-8393, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.8 years (25,132 days).
Specimen TCGA-58-8393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 762ffded-28b2-4343-8325-e8bebca133e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-8393-10A (Blood Derived Normal), aliquot TCGA-58-8393-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e92a0e3c-7ad3-46ac-b7db-2ed2402bdff1

The open-access MAF lists 288 somatic variants for this specimen: 221 protein-altering or splice-affecting, 64 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 196, Silent 64, Nonsense Mutation 17, Splice Site 4, RNA 2, In Frame Del 2, Translation Start Site 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.92_94del p.G31del | In Frame Del (DEL) | VAF 14/34 reads (41%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51025106, COSV99258111; called by muse, mutect2
- AADAT | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100528734; called by muse, mutect2, varscan2
- ABCA9 | c.4621C>T p.Q1541* | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | catalogued as COSV100382730; called by muse, mutect2, varscan2
- ABCF2 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99734948; called by muse, mutect2, varscan2
- ACSS3 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54097958, COSV99698377, COSV99699552; called by muse, mutect2, varscan2
- ADAMTS12 | c.4766A>G p.Q1589R | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100711737; called by muse, mutect2, varscan2
- ADCK1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99452771; called by muse, mutect2, varscan2
- AHCTF1 | c.2687G>C p.R896T (on ENST00000366508; = p.R870T on NM_015446.5) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100404506; called by muse, mutect2, varscan2
- AL592490.1 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV101308296; called by muse, mutect2
- ALDH1L1 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV99857587; called by muse, mutect2, varscan2
- ANKRD13C | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as COSV52034448, COSV99257792; called by muse, mutect2, varscan2
- AOC1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs781356328, COSV62868175; called by muse, mutect2, varscan2
- ARAP2 | c.3751C>A p.Q1251K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100395322; called by muse, mutect2
- ARHGAP21 | c.1987C>T p.Q663* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100256737; called by muse, mutect2, varscan2
- ATG4A | c.467+1G>C p.X156_splice | Splice Site (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100619887; called by muse, mutect2, varscan2
- ATP7A | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | catalogued as COSV100431802; called by muse, mutect2
- ATP8B3 | c.2896C>G p.Q966E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV100035067; called by muse, mutect2, varscan2
- B4GALNT1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100247348; called by muse, mutect2, varscan2
- B4GALNT2 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | catalogued as COSV100302810; called by muse, mutect2, varscan2
- BACH2 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100001201; called by muse, mutect2, varscan2
- BCAT1 | c.1127G>C p.R376T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV99679065; called by muse, mutect2
- BIRC6 | c.7363C>T p.Q2455* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV101428397, COSV101429047; called by muse, mutect2, varscan2
- BNIP2 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99985923; called by muse, mutect2, varscan2
- C2orf16 | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV101284442; called by muse, mutect2, varscan2
- CAGE1 | c.1359G>C p.E453D (on ENST00000512086; = p.E317D on NM_205864.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV99700245; called by muse, mutect2, varscan2
- CAMSAP3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371973765, COSV99350515; called by muse, mutect2, varscan2
- CASR | c.1890G>T p.E630D (on ENST00000490131; = p.E707D on NM_000388.4) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV99949525; called by muse, mutect2, varscan2
- CCDC136 | c.2086C>G p.Q696E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99923317; called by muse, mutect2, varscan2
- CDK11B | c.2016G>C p.K672N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV100478308; called by muse, mutect2, varscan2
- CELSR3 | c.6251C>G p.S2084C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51130867, COSV99375191; called by muse, mutect2, varscan2
- CENPE | c.6925G>T p.A2309S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV99479361; called by muse, varscan2
- CEP57L1 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.841); catalogued as COSV100425988, COSV61244206; called by muse, mutect2, varscan2
- CFHR4 | c.1537C>A p.H513N (on ENST00000367416 / NM_001201551.2; = p.H267N on NM_006684.5) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99259849; called by mutect2, varscan2
- CHRNA1 | c.1429G>A p.E477K (on ENST00000261007 / NM_001039523.3; = p.E452K on NM_000079.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); catalogued as COSV99650754; called by muse, mutect2, varscan2
- CHRNB4 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199599011, COSV55717279, COSV99929333; called by muse, mutect2, varscan2
- CNOT1 | c.5444C>T p.S1815F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99801414; called by muse, mutect2, varscan2
- COA3 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV99891692; called by muse, mutect2, varscan2
- CSMD1 | c.4420C>T p.P1474S (on ENST00000520002; = p.P1473S on NM_033225.6) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV100154416; called by muse, mutect2, varscan2
- CYBB | c.1075G>T p.G359W | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960455, COSV101059833; called by muse, mutect2, varscan2
- CYP11B1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs181764014, COSV52826182, COSV99455789; called by muse, mutect2, varscan2
- CYP2F1 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.821); catalogued as COSV100463044; called by muse, mutect2, varscan2
- DACH1 | c.1591+1G>A p.X531_splice (on ENST00000619232 / NM_001366712.1; = p.X479_splice on NM_080759.6) | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57501819; called by muse, mutect2, varscan2
- DBH | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV99708152; called by muse, mutect2, varscan2
- DCLRE1C | c.1808C>G p.S603C (on ENST00000378278 / NM_001350965.2; = p.S488C on NM_022487.4) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV57955622; called by muse, mutect2, varscan2
- DCX | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.396); catalogued as COSV100576789; called by muse, mutect2, varscan2
- DIAPH1 | c.3478G>C p.E1160Q | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99527330; called by muse, mutect2, varscan2
- DIAPH2 | c.2263C>T p.L755F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61271115; called by muse, mutect2, varscan2
- DIPK2A | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1414622462, COSV100237486; called by muse, mutect2
- DNAAF2 | c.786C>G p.H262Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV100024258; called by muse, mutect2, varscan2
- DNAJB11 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV54004008, COSV99408766; called by muse, mutect2, varscan2
- DPY19L1 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV100204837, COSV100205070; called by muse, mutect2, varscan2
- EP300 | c.2247G>A p.M749I | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as COSV99610009; called by muse, mutect2, varscan2
- EPHB1 | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV101214628, COSV67654756; called by muse, mutect2, varscan2
- ERBIN | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.342); catalogued as COSV99397931; called by muse, mutect2, varscan2
- ERCC4 | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100319150, COSV61313018; called by muse, mutect2
- ERICH3 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV58599124, COSV58615824; called by muse, mutect2, varscan2
- ESF1 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.423); catalogued as COSV99176555; called by muse, mutect2, varscan2
- FAM47C | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as rs782735363, COSV100792977; called by muse, mutect2, varscan2
- FBXO24 | c.45G>C p.K15N (on ENST00000241071 / NM_033506.3; = p.K53N on NM_012172.5) | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as COSV99575743; called by muse, mutect2, varscan2
- FES | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs576327466, COSV99184807; called by muse, mutect2, varscan2
- FEZ1 | c.975G>C p.Q325H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs181830556, COSV54027861, COSV99631413; called by muse, mutect2, varscan2
- FHL1 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100600874; called by muse, mutect2, varscan2
- FNIP1 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100330629; called by muse, mutect2, varscan2
- GAGE1 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.077); catalogued as rs144282981; called by muse, mutect2, varscan2
- GFPT1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61946637; called by muse, mutect2
- GHR | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as rs34283856; called by muse, mutect2, varscan2
- GLI1 | c.2251C>G p.L751V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV57364860, COSV99953633; called by muse, mutect2, varscan2
- GLI1 | c.2713C>G p.Q905E | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs760909851, COSV57364174; called by muse, mutect2, varscan2
- GOLIM4 | c.1949A>T p.D650V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV100463536; called by muse, mutect2, varscan2
- GPR84 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV57209296, COSV57209477; called by muse, mutect2, varscan2
- H2BC18 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.338); catalogued as COSV100516198; called by muse, mutect2, varscan2
- HMCN1 | c.8687C>G p.S2896C | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99636696; called by muse, mutect2
- HNRNPUL1 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647657; called by muse, mutect2, varscan2
- HOXA1 | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547449; called by muse, mutect2, varscan2
- HRNR | c.8200G>C p.D2734H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV100913580; called by muse, mutect2, varscan2
- HSD17B1 | c.404C>G p.S135W | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99864760; called by muse, mutect2, varscan2
- HSPA6 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100554370; called by muse, mutect2, varscan2
- HSPB8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs757293016, COSV56136872, COSV56137127, COSV56137340; called by muse, mutect2, varscan2
- HUWE1 | c.567+1G>A p.X189_splice | Splice Site (SNP) | VAF 28/135 reads (21%) | catalogued as COSV99474503; called by muse, mutect2, varscan2
- IFT172 | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99563485; called by muse, mutect2, varscan2
- IL21R | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as COSV100560636; called by muse, mutect2, varscan2
- IMPA2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV99302752; called by muse, mutect2
- IMPG1 | c.258G>C p.M86I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100886732, COSV64062317; called by muse, mutect2, varscan2
- INTS6L | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100878337; called by muse, mutect2, varscan2
- IQCG | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 96/501 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99502777; called by muse, mutect2, varscan2
- IRF4 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs752393433, COSV66704538; called by muse, mutect2, varscan2
- IRGQ | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.199); catalogued as COSV100338271; called by muse, mutect2, varscan2
- ISM2 | c.360G>C p.L120F | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99376914; called by muse, mutect2
- ITGA4 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV99276876; called by muse, mutect2, varscan2
- ITPRIPL1 | c.509C>G p.S170C (on ENST00000439118 / NM_001008949.3; = p.S178C on NM_178495.6) | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as COSV100742255; called by muse, mutect2, varscan2
- IYD | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV99989240, COSV99990193; called by muse, mutect2, varscan2
- KBTBD7 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101068211, COSV65266448; called by muse, mutect2, varscan2
- KCNB1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.623); catalogued as COSV100870604; called by muse, mutect2
- KCND2 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.259); catalogued as COSV100478961; called by muse, mutect2, varscan2
- KIRREL1 | c.864G>C p.E288D | Missense Mutation (SNP) | VAF 32/351 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV100780157; called by muse, mutect2
- KLHL4 | c.2077C>T p.Q693* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV64147316; called by muse, mutect2, varscan2
- KNL1 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100707118, COSV61156095; called by muse, mutect2, varscan2
- KPNB1 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99268447; called by muse, mutect2, varscan2
- LGMN | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100606028; called by muse, mutect2, varscan2
- LMNB2 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.207); catalogued as rs777988017, COSV99296131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPAR4 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV101425175; called by muse, mutect2, varscan2
- MAGEA11 | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV60758075; called by muse, mutect2, varscan2
- MATN4 | c.1603G>A p.E535K (on ENST00000372754; = p.E494K on NM_003833.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | PolyPhen benign (0.045); catalogued as COSV61351627; called by muse, mutect2, varscan2
- MBTPS2 | c.1047T>G p.N349K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV101068599; called by muse, mutect2, varscan2
- MEF2B | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99365143; called by muse, mutect2
- MIDN | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758934723, COSV56294380; called by mutect2, varscan2
- MOAP1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs774098182, COSV99365838; called by muse, mutect2
- MOCS1 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100418886; called by muse, mutect2, varscan2
- MTCL1 | c.2383G>A p.E795K (on ENST00000306329 / NM_001378206.1; = p.E435K on NM_015210.4) | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100095721; called by muse, mutect2, varscan2
- MTG1 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100448962; called by muse, mutect2, varscan2
- MYO1E | c.1563G>T p.R521S | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as COSV55686741, COSV99896760; called by muse, mutect2, varscan2
- NCAM2 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99522923; called by muse, mutect2
- NCOR2 | c.2263C>G p.H755D | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100657947, COSV62295282; called by muse, mutect2
- NEDD4L | c.2020G>C p.E674Q (on ENST00000400345 / NM_001144967.3; = p.E654Q on NM_015277.6) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99896783; called by muse, mutect2, varscan2
- NEXMIF | c.1752G>C p.L584F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99282077; called by muse, mutect2, varscan2
- NFIL3 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99907067; called by muse, mutect2
- NFKB1 | c.234G>C p.K78N (on ENST00000394820 / NM_001382627.1; = p.K79N on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99897959; called by muse, mutect2, varscan2
- NRAP | c.5172G>C p.K1724N (on ENST00000359988 / NM_001322945.2; = p.K1689N on NM_006175.4) | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV100668113; called by muse, mutect2, varscan2
- NUTM1 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV100149227, COSV59217368; called by muse, mutect2
- OBSCN | c.13150G>A p.E4384K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV52750931; called by muse, mutect2, varscan2
- OR5R1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.58); catalogued as COSV100393614; called by muse, mutect2, varscan2
- OSGEPL1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs767725539, COSV99918532; called by muse, mutect2, varscan2
- OSGEPL1 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99918534; called by muse, mutect2, varscan2
- PAM | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV57212526, COSV99173887; called by muse, mutect2, varscan2
- PARP15 | c.1933G>A p.D645N (on ENST00000464300 / NM_001113523.3; = p.D411N on NM_152615.2) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV100117246; called by muse, mutect2, varscan2
- PCDH10 | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99994647; called by muse, mutect2, varscan2
- PCDH9 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100124014; called by muse, mutect2
- PDZD2 | c.3347C>T p.S1116F | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1238224368, COSV99226940; called by muse, varscan2
- PDZD2 | c.7263G>A p.M2421I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV99226945; called by muse, mutect2, varscan2
- PEX5L | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99830097; called by muse, mutect2, varscan2
- PHACTR4 | c.1490C>T p.S497L (on ENST00000373839 / NM_001350159.2; = p.S507L on NM_023923.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV100868502; called by muse, mutect2, varscan2
- PHACTR4 | c.1945G>C p.E649Q (on ENST00000373839 / NM_001350159.2; = p.E659Q on NM_023923.4) | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV100868504; called by muse, mutect2, varscan2
- PIBF1 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58322818; called by muse, mutect2, varscan2
- PIK3IP1 | c.618G>C p.Q206H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as rs1311917430, COSV99314262; called by muse, mutect2, varscan2
- PLCB2 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99542735; called by muse, mutect2, varscan2
- PLCB2 | c.2004C>G p.F668L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV99542738; called by muse, mutect2, varscan2
- PLXNA2 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV100886062; called by muse, mutect2, varscan2
- POMZP3 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.587); catalogued as rs1563806704, COSV99300701; called by muse, mutect2, varscan2
- PPP4R2 | c.170T>G p.M57R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99866390; called by muse, varscan2
- PRAG1 | c.3841G>T p.D1281Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100422925; called by muse, mutect2, varscan2
- PRR19 | c.974G>A p.W325* | Nonsense Mutation (SNP) | VAF 52/317 reads (16%) | catalogued as COSV100004175; called by muse, mutect2, varscan2
- PTCHD4 | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs769671626, COSV100261787; called by muse, mutect2, varscan2
- PTDSS1 | c.848_850del p.S283del | In Frame Del (DEL) | VAF 39/216 reads (18%) | catalogued as rs1209134147; called by pindel, varscan2
- PYGM | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.357); catalogued as rs779392056, COSV99377678; called by muse, mutect2, varscan2
- RALGAPA2 | c.4948G>A p.A1650T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376669695, COSV52496351; called by muse, mutect2
- RANBP10 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100449518; called by muse, varscan2
- RASA2 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53936890, COSV99656908; called by muse, mutect2
- RB1CC1 | c.4015G>T p.E1339* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99213112; called by muse, mutect2
- RBM27 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV99505618, COSV99506698; called by muse, mutect2, varscan2
- REG1A | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99287009; called by muse, mutect2, varscan2
- REPS1 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99239089; called by muse, mutect2, varscan2
- RFX7 | c.3637G>C p.E1213Q (on ENST00000559447 / NM_001368074.1; = p.E1310Q on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100429496; called by muse, mutect2, varscan2
- RGS9 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.038); catalogued as rs375807747; called by muse, mutect2, varscan2
- RO60 | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100814453; called by muse, mutect2, varscan2
- RP1L1 | c.2840C>G p.S947C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101223684, COSV66755624; called by muse, mutect2, varscan2
- SALL1 | c.2440G>C p.D814H | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV99177087, COSV99192141; called by muse, mutect2
- SCCPDH | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as COSV100829749; called by muse, mutect2, varscan2
- SEMA4C | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV100561205; called by muse, mutect2, varscan2
- SERPINI1 | c.384G>T p.M128I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99855468; called by muse, mutect2, varscan2
- SFMBT2 | c.1426G>C p.A476P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100739726; called by muse, mutect2, varscan2
- SGK2 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776084733, COSV58313765; called by muse, mutect2, varscan2
- SH3GLB1 | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV100990827, COSV65281163; called by muse, mutect2, varscan2
- SIGLEC1 | c.4064G>T p.R1355L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV52474381, COSV99171421; called by muse, mutect2, varscan2
- SLC12A1 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57711936; called by muse, mutect2, varscan2
- SLC25A38 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99827955; called by muse, mutect2, varscan2
- SLC26A3 | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100385329, COSV60640581; called by muse, mutect2, varscan2
- SLC27A5 | c.1600G>T p.G534W | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780522661, COSV99564653; called by muse, mutect2, varscan2
- SLC2A4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100435384; called by muse, mutect2, varscan2
- SLIT3 | c.3973T>C p.S1325P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100270335; called by muse, mutect2, varscan2
- SLITRK4 | c.173G>A p.W58* | Nonsense Mutation (SNP) | VAF 24/143 reads (17%) | catalogued as COSV100567543; called by muse, mutect2, varscan2
- SON | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV99280060; called by muse, mutect2, varscan2
- SPATA31E1 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV100351169; called by muse, mutect2, varscan2
- SPEN | c.5041G>C p.E1681Q | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as COSV101005670, COSV65357675; called by muse, mutect2
- ST6GALNAC3 | c.140G>C p.W47S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | PolyPhen benign (0.007); catalogued as COSV100085584; called by muse, mutect2, varscan2
- STAR | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV99379220; called by muse, mutect2, varscan2
- STAT1 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV100738902; called by muse, mutect2, varscan2
- SYNE1 | c.9462G>A p.W3154* (on ENST00000367255 / NM_182961.4; = p.W3161* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 55/202 reads (27%) | catalogued as COSV99581282; called by muse, mutect2, varscan2
- SYT16 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101413690, COSV70858044; called by muse, mutect2, varscan2
- TADA3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100113129; called by muse, mutect2
- TAF8 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs200166840; called by muse, varscan2
- TDRKH | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.437); catalogued as rs1258875787, COSV100918052; called by muse, mutect2
- TEP1 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53001766; called by muse, mutect2, varscan2
- TEX13B | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.025); catalogued as rs756388958, COSV57202445; called by muse, mutect2, varscan2
- TEX14 | c.3517G>C p.D1173H (on ENST00000240361 / NM_001201457.2; = p.D1127H on NM_031272.5) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99543790; called by muse, mutect2, varscan2
- TG | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV99603550; called by muse, mutect2, varscan2
- TMEM74 | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99865966; called by muse, varscan2
- TMEM74 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV99865968; called by muse, mutect2, varscan2
- TPH2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767269211, COSV100422423; called by muse, mutect2, varscan2
- TREM1 | c.160G>C p.A54P | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484279081, COSV99776354, COSV99776355; called by muse, mutect2, varscan2
- TRIM6 | c.477G>C p.E159D | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV99546884; called by muse, mutect2, varscan2
- TRIM69 | c.1399A>G p.T467A (on ENST00000329464 / NM_182985.5; = p.T308A on NM_080745.5) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100274434, COSV57805549; called by muse, mutect2, varscan2
- TRPC5 | c.1869G>A p.M623I | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV53290635; called by muse, varscan2
- TRPC5 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 112/573 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.099); catalogued as rs778802286, COSV53297299; called by muse, varscan2
- TRPS1 | c.2956G>A p.D986N (on ENST00000220888 / NM_001330599.2; = p.D999N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV55253116, COSV99634958; called by muse, mutect2, varscan2
- TSNAX | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 18/146 reads (12%) | catalogued as COSV100791146; called by muse, mutect2, varscan2
- TUBE1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.378); catalogued as COSV100898330; called by muse, mutect2, varscan2
- UPF2 | c.3196G>A p.D1066N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as COSV100707480; called by muse, mutect2, varscan2
- USP34 | c.7154G>A p.R2385K | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.782); catalogued as COSV101277255; called by muse, mutect2, varscan2
- XCL2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV100892272; called by muse, mutect2, varscan2
- XKR4 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.058); catalogued as COSV100534235; called by muse, mutect2, varscan2
- ZC3H12B | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100162106, COSV59048086; called by muse, mutect2, varscan2
- ZDBF2 | c.1634C>A p.P545Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV100985616; called by muse, mutect2, varscan2
- ZDHHC16 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59133775; called by muse, mutect2, varscan2
- ZFP2 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100797138, COSV63726064; called by muse, mutect2, varscan2
- ZNF180 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 39/143 reads (27%) | catalogued as COSV99660097; called by muse, mutect2, varscan2
- ZNF254 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100741802, COSV104419135; called by muse, mutect2
- ZNF274 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100465560; called by muse, mutect2
- ZNF319 | c.1215G>C p.Q405H | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99540508; called by muse, mutect2, varscan2
- ZNF420 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV100421552; called by muse, mutect2
- ZNF462 | c.4240G>A p.E1414K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99470476, COSV99473498; called by muse, mutect2, varscan2
- ZNF544 | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765962490, COSV99517296; called by muse, mutect2, varscan2
- ZNF550 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs761476303, COSV100286872; called by muse, mutect2, varscan2
- ZNF613 | c.1105G>T p.E369* (on ENST00000293471 / NM_001031721.4; = p.E333* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 21/129 reads (16%) | catalogued as rs1282180239, COSV99523008, COSV99523082; called by muse, mutect2, varscan2
- ZNF692 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100129411; called by muse, mutect2, varscan2
- ZNF749 | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.218); catalogued as COSV100494520; called by muse, mutect2, varscan2
- ZNF774 | c.1068C>G p.F356L | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100586487; called by muse, mutect2
- DUSP16 | c.531+1del p.X177_splice | Splice Site (DEL) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- ITCH | c.1629del p.M544Cfs*5 (on ENST00000262650 / NM_001257137.3; = p.M503Cfs*5 on NM_031483.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- AADAC | c.636C>T p.L212= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV99233541; called by muse, mutect2, varscan2
- ABCA1 | c.462C>T p.F154= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV101035790; called by muse, mutect2, varscan2
- AC005324.2 | c.660G>T p.G220= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs778777436, COSV100372112; called by muse, mutect2, varscan2
- AC109583.1 | c.630C>G p.L210= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100167989; called by muse, mutect2, varscan2
- ADAR | c.2541G>C p.L847= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV99425957, COSV99426825; called by muse, mutect2
- ALDOA | c.336C>T p.F112= (on ENST00000642816 / NM_001243177.4; = p.F58= on NM_184041.5) | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100582273; called by muse, mutect2, varscan2
- AQP11 | c.357G>A p.V119= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV100547407; called by muse, mutect2, varscan2
- ARFGEF1 | c.1947G>A p.E649= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99145138; called by muse, mutect2, varscan2
- ATP8B3 | c.2235C>T p.V745= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs1329894446, COSV100035072; called by muse, mutect2
- B4GALNT1 | c.267C>A p.L89= | Silent (SNP) | VAF 49/204 reads (24%) | catalogued as COSV100356555; called by muse, mutect2, varscan2
- CACNA1S | c.1809C>T p.A603= | Silent (SNP) | VAF 70/220 reads (32%) | catalogued as rs1173857453, COSV100755413; called by muse, mutect2, varscan2
- CD1A | c.870C>T p.I290= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs757980794, COSV56863635, COSV99192270; called by muse, mutect2, varscan2
- CDH19 | c.2013G>A p.R671= | Silent (SNP) | VAF 39/275 reads (14%) | catalogued as COSV100052456; called by muse, mutect2, varscan2
- CHKB | c.963G>A p.K321= | Silent (SNP) | VAF 43/220 reads (20%) | catalogued as COSV56416164, COSV56416443; called by muse, varscan2
- CIBAR1 | c.210G>C p.L70= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100844745; called by muse, mutect2, varscan2
- CLTB | c.510C>T p.I170= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs776517011, COSV60045452; called by muse, mutect2, varscan2
- CNKSR1 | c.918A>G p.P306= (on ENST00000374253 / NM_001297647.2; = p.P299= on NM_006314.3) | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as rs1161327766, COSV100836808; called by muse, mutect2, varscan2
- COG1 | c.2649G>A p.E883= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100245469; called by muse, mutect2, varscan2
- COQ6 | c.954C>T p.V318= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs1007858755, COSV99473744; called by muse, mutect2, varscan2
- CUL7 | c.2214G>A p.V738= | Silent (SNP) | VAF 58/231 reads (25%) | catalogued as rs549059005, COSV54815081; called by muse, mutect2, varscan2
- DHX34 | c.1779G>A p.L593= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100169959, COSV60895730; called by muse, mutect2, varscan2
- DIP2A | c.2092C>T p.L698= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100596387; called by muse, mutect2, varscan2
- EPB41 | c.600C>T p.S200= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100548442; called by muse, mutect2, varscan2
- ETV3 | c.381C>T p.F127= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100461184; called by muse, mutect2, varscan2
- FAM160A2 | c.741G>T p.V247= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as COSV99792572; called by muse, mutect2
- GRIA2 | c.771C>A p.V257= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV52389505, COSV99644749; called by muse, mutect2
- IKZF1 | c.510G>A p.E170= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100497785, COSV58786799; called by muse, mutect2, varscan2
- ITCH | c.66C>T p.I22= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV99393254; called by muse, mutect2, varscan2
- KDM1B | c.267A>G p.E89= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs753608249, COSV99924744; called by muse, mutect2, varscan2
- KDM5C | c.237G>A p.T79= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs370457010, COSV100855521; called by muse, mutect2, varscan2
- MANEA | c.295C>T p.L99= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV100721692; called by muse, mutect2
- MB21D2 | c.456C>G p.L152= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV101165198; called by muse, mutect2, varscan2
- MCM6 | c.469C>T p.L157= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV51466894; called by muse, mutect2, varscan2
- MED1 | c.1935C>T p.L645= | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as COSV100328200; called by muse, mutect2
- MED16 | c.1656C>T p.F552= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV99516377; called by muse, mutect2
- NBPF3 | c.843G>A p.G281= | Silent (SNP) | VAF 40/255 reads (16%) | catalogued as COSV100559101; called by muse, mutect2, varscan2
- NFATC4 | c.2223C>T p.F741= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs147125766, COSV51599760; called by muse, mutect2
- NLRP4 | c.2070C>G p.L690= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as rs374795883, COSV56708988; called by muse, mutect2
- NOVA2 | c.1236G>A p.A412= | Silent (SNP) | VAF 49/240 reads (20%) | catalogued as COSV99611742; called by muse, mutect2, varscan2
- NXF1 | c.777C>T p.I259= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99586512; called by muse, mutect2
- OCEL1 | c.168G>A p.P56= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs753758340, COSV99285839; called by muse, varscan2
- OR10J3 | c.348C>T p.L116= | Silent (SNP) | VAF 17/202 reads (8%) | catalogued as COSV59954507; called by muse, mutect2
- PALD1 | c.333G>T p.V111= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99698732; called by muse, mutect2, varscan2
- PASD1 | c.2301T>C p.R767= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV100949684; called by muse, mutect2, varscan2
- PCDH15 | c.1794C>T p.I598= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV57303833, COSV57330842; called by muse, mutect2, varscan2
- PCNX1 | c.141C>T p.F47= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99457469; called by muse, mutect2, varscan2
- PIAS3 | c.42C>T p.F14= | Silent (SNP) | VAF 47/279 reads (17%) | catalogued as rs782441875, COSV100992782; called by muse, mutect2, varscan2
- PLXNA2 | c.3066G>C p.V1022= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100886060; called by muse, mutect2
- PREX2 | c.3306C>T p.I1102= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as COSV99910313; called by muse, mutect2, varscan2
- PRMT9 | c.333C>G p.L111= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100482407; called by muse, mutect2, varscan2
- PTPRD | c.2892C>T p.P964= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs376193969; called by muse, mutect2, varscan2
- RANBP10 | c.1347G>A p.E449= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100449516; called by muse, varscan2
- RBM42 | c.1437G>C p.L479= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99387257; called by muse, mutect2, varscan2
- SFTPD | c.483C>T p.L161= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs987052380, COSV64852599; called by muse, mutect2, varscan2
- SLC15A4 | c.1176G>A p.L392= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV57160783, COSV57163325; called by muse, mutect2, varscan2
- SLC26A6 | c.2094G>A p.E698= | Silent (SNP) | VAF 83/291 reads (29%) | catalogued as COSV100258805; called by muse, mutect2, varscan2
- SLC27A2 | c.1050C>T p.V350= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as COSV99983129; called by muse, mutect2, varscan2
- SLCO4A1 | c.465C>G p.L155= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV99415182; called by muse, mutect2
- SPATC1 | c.477G>A p.L159= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV66298622; called by muse, mutect2, varscan2
- SSTR1 | c.375C>T p.F125= | Silent (SNP) | VAF 93/333 reads (28%) | catalogued as rs1340536524, COSV99943187; called by muse, mutect2, varscan2
- TBC1D25 | c.1899C>T p.I633= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as COSV100952247; called by muse, mutect2, varscan2
- TMC6 | c.1561C>T p.L521= | Silent (SNP) | VAF 51/133 reads (38%) | catalogued as rs751047936, COSV100130410; called by muse, varscan2
- TRIM58 | c.783C>T p.V261= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100825332; called by muse, mutect2
- WNT5B | c.780G>A p.K260= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV60198007; called by muse, mutect2, varscan2
- EXOC3 | chr5:442804 A>G | 5'Flank (SNP) | VAF 13/85 reads (15%) | catalogued as rs763548236; called by muse, mutect2
- MALAT1 | n.116C>G | RNA (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- OR2W5 | n.1269C>G | RNA (SNP) | VAF 41/132 reads (31%) | catalogued as rs763698455; called by muse, mutect2, varscan2
